CPTAC case C3L-06774 — Stomach — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6b0f230f-91ea-4eb9-a89e-66f3cd82db59

Demographics
Sex at birth: male; Race: white; Year of birth: 1971; Vital status: Alive; Country of birth: Ukraine.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Gastric antrum; Age at diagnosis: 47.7 years (17,414 days); Year of diagnosis: 2019; AJCC staging edition: 8th; AJCC pathologic T: T2; AJCC pathologic N: N2; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Residual disease: R0; Days to last known disease status: 399 days (1.1 years); Days to last follow up: 399 days (1.1 years); Tumor focality: Multifocal.
   Pathology details: Greatest tumor dimension: 4.5 cm; Lymph node involvement: Positive; Lymph nodes positive: 3; Lymph nodes tested: 8.

Follow-up (1 entry)
- Days to follow up: 399 days (1.1 years); Karnofsky performance status: 80; ECOG performance status: 2.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-06774-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 381 days (1.0 years); Initial weight: 770 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-06774-23: Section location: Antrum; Percent tumor nuclei: 60; Percent necrosis: 0.
- Sample C3L-06774-05: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 381 days (1.0 years); Initial weight: 660 mg; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-06774-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 381 days (1.0 years); Method of sample procurement: Blood Draw.
